Somatic mutation profile of tumor specimen TCGA-DX-A1L2-01A (aliquot TCGA-DX-A1L2-01A-22D-A24N-09) from TCGA case TCGA-DX-A1L2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.6 years (28,692 days).
Specimen TCGA-DX-A1L2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96d723c7-3857-4d56-981e-073157b70d72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1L2-10A (Blood Derived Normal), aliquot TCGA-DX-A1L2-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e45addcc-0896-472e-b843-16d0f6234d48

The open-access MAF lists 142 somatic variants for this specimen: 98 protein-altering or splice-affecting, 37 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 37, RNA 4, Splice Site 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 2, In Frame Ins 1, Intron 1, 3'UTR 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.7063C>T p.R2355W | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs193922803, CM021676; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- BLVRB | c.621G>C p.*207Yext*? | Nonstop Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99648023; called by muse, mutect2, varscan2
- CACNA1F | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs782537377, COSV100545100; called by muse, mutect2, varscan2
- CAMTA1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1325441787; called by muse, mutect2, varscan2
- CR2 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV65507858; called by muse, mutect2
- CRISP3 | c.359A>T p.D120V (on ENST00000371159 / NM_001368123.1; = p.D102V on NM_006061.4) | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV99538499; called by muse, mutect2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 4/28 reads (14%) | catalogued as rs782442161; called by mutect2, pindel
- EFHB | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV55550983; called by muse, mutect2
- EPN2 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100127259; called by muse, mutect2
- FRMD4B | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1271597728; called by muse, mutect2, varscan2
- GIGYF1 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.259); catalogued as rs1451723425, COSV51939776; called by muse, mutect2, varscan2
- GPRC5C | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV100702837; called by muse, mutect2, varscan2
- GPRC5C | c.278C>T p.A93V (on ENST00000652232; = p.A48V on NM_018653.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as rs372728157; called by muse, mutect2, varscan2
- GUSB | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs377615121, COSV59221150; called by muse, mutect2, varscan2
- HIGD1B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs142682593; called by muse, mutect2, varscan2
- HOXB1 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV53317994; called by muse, mutect2, varscan2
- IBTK | c.2790+1G>A p.X930_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as rs1259175805, COSV100089764; called by muse, mutect2, varscan2
- IFI6 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100191546; called by muse, mutect2, varscan2
- KIAA2013 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100927103; called by muse, mutect2
- KIAA2013 | c.1034-1G>A p.X345_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100927104; called by muse, mutect2, varscan2
- LRRC37A3 | c.1115A>T p.E372V | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV100140724; called by muse, mutect2
- LUC7L | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as COSV53457134; called by muse, mutect2, varscan2
- MEGF6 | c.3763G>A p.G1255S | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748271706, COSV53895177; called by muse, mutect2, varscan2
- NLRP4 | c.721A>C p.N241H | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1471057048; called by muse, mutect2, varscan2
- OR11H1 | c.766T>A p.Y256N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99421484; called by muse, mutect2, varscan2
- PADI4 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375905749, COSV64924119; called by muse, mutect2, varscan2
- PCDHB6 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); catalogued as rs1554277512; called by muse, mutect2, varscan2
- PCYOX1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs200244897; called by muse, mutect2, varscan2
- PDZD2 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223128; called by muse, mutect2
- PLEKHA7 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs1274582739, COSV100261771; called by muse, mutect2
- PLPPR2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1238992669, COSV52258729, COSV52259089; called by muse, mutect2, varscan2
- PREX2 | c.3533G>A p.G1178E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55775786, COSV55786310, COSV99905418; called by muse, mutect2, varscan2
- SDHA | c.1721G>C p.C574S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.021); catalogued as COSV99371089; called by muse, mutect2, varscan2
- STYXL2 | c.1973C>G p.P658R | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770607161; called by muse, mutect2, varscan2
- STYXL2 | c.2602C>G p.L868V | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs753485339; called by muse, mutect2, varscan2
- TAGLN2 | c.234_235insTTA p.K78_K79insL | In Frame Ins (INS) | VAF 19/103 reads (18%) | catalogued as COSV100230908; called by mutect2, pindel, varscan2
- TBX21 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1292283769; called by muse, mutect2, varscan2
- TCTE1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.467); catalogued as rs147183186; called by muse, mutect2, varscan2
- TDRD6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs766526554; called by muse, mutect2, varscan2
- TECTA | c.4593C>A p.F1531L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV50698799; called by muse, mutect2, varscan2
- TMPRSS5 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1368822178; called by muse, mutect2, varscan2
- TRMT1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs900109858; called by muse, mutect2, varscan2
- TUBA3C | c.952T>A p.L318M | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.666); catalogued as COSV68029116; called by muse, varscan2
- UBASH3A | c.631A>G p.R211G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1218862274; called by muse, mutect2, varscan2
- UBB | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as COSV100141560; called by muse, mutect2, varscan2
- UNC13A | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs1402835470, COSV53201008; called by muse, mutect2, varscan2
- ZBED9 | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs199908707, COSV71729825; called by muse, mutect2, varscan2
- ADAMTS1 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AKAP12 | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANXA10 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- ATRX | c.829dup p.V277Gfs*5 | Frame Shift Ins (INS) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- BCAN | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- CCR3 | c.957C>G p.H319Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH26 | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CDKL5 | c.2873T>A p.I958N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRM4 | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CPA1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- DPP9 | c.1408G>C p.E470Q (on ENST00000598800; = p.E499Q on NM_139159.5) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EDC4 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ETV3L | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- IFNL2 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- INF2 | c.2350A>C p.T784P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- KIAA2013 | c.1833G>C p.K611N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF5A | c.1885T>C p.C629R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- LY9 | c.1833A>G p.G611= | Splice Region (SNP) | VAF 5/146 reads (3%) | called by muse, mutect2
- MAN1C1 | c.1231A>G p.K411E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MARCHF6 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED17 | c.1100A>T p.H367L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MTMR4 | c.1812A>G p.R604= | Splice Region (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- MYH14 | c.4670C>A p.A1557E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYH4 | c.5723A>G p.E1908G | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2
- NPTXR | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2E1 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NRP2 | c.781T>A p.S261T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NRP2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTP | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- PARP1 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- PCDHA1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- PCLO | c.11497T>A p.Y3833N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA6 | c.2501A>C p.Q834P (on ENST00000414982 / NM_001166111.2; = p.Q786P on NM_006702.5) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- PPOX | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 98/495 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PRTG | c.2887C>A p.L963I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCN4A | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SHOC1 | c.300C>G p.H100Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIGLEC5 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SLC6A16 | c.829T>G p.C277G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- SLIT3 | c.3074A>T p.N1025I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.296); called by muse, mutect2
- SP3 | c.1525dup p.T509Nfs*4 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- ST18 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STYXL2 | c.2127C>A p.N709K | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- STYXL2 | c.2464C>G p.P822A | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SYNRG | c.2824A>G p.T942A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPC7 | c.217T>A p.C73S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TUBG1 | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- USP24 | c.7817T>C p.M2606T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WDR46 | c.1477A>C p.S493R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF704 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZZEF1 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM17 | c.2190T>C p.F730= | Silent (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- ADAM17 | c.420C>A p.I140= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.585A>C p.G195= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- BOD1L1 | c.8838G>C p.R2946= | Silent (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- C1RL | c.1083C>T p.P361= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs201239060, COSV56924977; called by muse, mutect2, varscan2
- C22orf42 | c.240C>T p.D80= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs761214648, COSV66076324; called by mutect2, varscan2
- CD300E | c.546G>T p.L182= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- CHRNB1 | c.1467C>T p.D489= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs1362533670; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOK2 | c.867T>C p.A289= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- EXOC6B | c.2274G>C p.R758= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- F10 | c.1134G>A p.K378= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- FBXW10 | c.762C>T p.P254= | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2
- FOXG1 | c.1347G>T p.S449= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV57396101; called by mutect2, varscan2
- FSTL5 | c.2160C>T p.Y720= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- HDLBP | c.1584A>G p.E528= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- JPH2 | c.879C>T p.G293= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1533G>A p.V511= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100927102; called by muse, mutect2, varscan2
- MTTP | c.1098T>G p.A366= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- NR1I3 | c.873G>A p.E291= (on ENST00000367982 / NM_001077480.3; = p.E287= on NM_005122.5) | Silent (SNP) | VAF 15/381 reads (4%) | called by muse, mutect2
- PCP4L1 | c.36C>T p.T12= | Silent (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- PHEX | c.1665C>T p.L555= | Silent (SNP) | VAF 25/32 reads (78%) | called by muse, mutect2, varscan2
- PKLR | c.345G>A p.A115= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61361767; called by muse, mutect2, varscan2
- PMPCB | c.882G>A p.A294= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs76757936, COSV99971215; called by muse, mutect2, varscan2
- PPP1R13B | c.1857C>G p.T619= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1350223689; called by muse, mutect2
- PRMT8 | c.652C>A p.R218= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54212047; called by muse, mutect2, varscan2
- PTPRB | c.780G>A p.L260= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- SGO2 | c.2829T>C p.F943= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100764568; called by muse, mutect2
- SHANK1 | c.198C>T p.D66= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs545121253, COSV53242370; called by muse, mutect2, varscan2
- SLIT3 | c.3072T>A p.P1024= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2
- SYNE1 | c.23739C>G p.V7913= (on ENST00000367255 / NM_182961.4; = p.V7842= on NM_033071.3) | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV54969357; called by muse, varscan2
- SYT6 | c.1281C>G p.V427= (on ENST00000610222 / NM_001366225.1; = p.V342= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- TBX2 | c.381C>T p.I127= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- TDO2 | c.795G>C p.L265= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- TGIF2LX | c.198C>T p.R66= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99383111; called by muse, mutect2, varscan2
- TXNDC9 | c.261G>A p.K87= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV51812080, COSV99959933; called by muse, mutect2, varscan2
- ZFYVE21 | c.498G>A p.Q166= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- ZNF419 | c.378A>G p.Q126= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99691682; called by muse, mutect2
- AC024940.1 | n.4981C>A | RNA (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- LINC02877 | n.381C>T | RNA (SNP) | VAF 11/40 reads (28%) | catalogued as rs1202418606; called by muse, mutect2
- MFSD4B | c.*235C>G | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as COSV64348559; called by muse, mutect2, varscan2
- MIR1197 | n.81C>T | RNA (SNP) | VAF 58/149 reads (39%) | catalogued as rs554417979; called by muse, mutect2, varscan2
- MIR129-1 | n.19G>C | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- NMNAT2 | c.86-10892T>G | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- NUTM2D | chr10:87367352 C>G | 3'Flank (SNP) | VAF 32/136 reads (24%) | catalogued as rs761880369, COSV67746203; called by muse, mutect2, varscan2
